Gene-level copy-number profile of tumor specimen TCGA-06-0152-01A from TCGA case TCGA-06-0152, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.0 years (24,844 days).
Specimen TCGA-06-0152-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.4bec56ce-7b7c-4d38-9e60-52abf9b56ea7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0152-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/60ace7ff-c287-419d-a890-87d59a88111b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 208; copy number 2: 4,089; copy number 3: 14,565; copy number 4: 29,471; copy number 5: 7,269; copy number 6: 4,074; copy number 7: 46; copy number 8: 32; copy number 9: 7; copy number 14: 2; copy number 20: 6; copy number 22: 3; copy number 40: 8; copy number 61: 1; copy number 63: 9; copy number 67: 6; copy number 70: 17; copy number 77: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0152-01A-02D-0310-01): tumor purity 0.67, ploidy 3.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 65 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,330,670–55,595,006, 23 genes, copy number 9–70 (within-gene range 3–70): LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2.
- chr12:57,738,013–57,797,554, 8 genes, copy number 40 (within-gene range 2–40): TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3.
- chr12:62,139,999–62,145,643, 1 gene, copy number 9: AC078789.1.
- chr12:64,146,388–64,397,065, 5 genes, copy number 77 (within-gene range 2–77): AC025576.1, C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P.
- chr12:64,266,413–64,266,766, 1 gene, copy number 77: OOEPP2.
- chr12:65,134,688–65,248,355, 3 genes, copy number 22: APOOP3, LEMD3, AC026124.2.
- chr12:68,143,318–68,143,690, 1 gene, copy number 61: AC007458.1.
- chr12:68,746,125–68,850,686, 6 genes, copy number 67: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr12:69,239,569–69,699,476, 17 genes, copy number 14–63 (within-gene range 3–63): CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3.

Autosomal genes at a single copy (total copy number 1): 208. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
